CCDI case PBBPNE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/84a149fe-7cfc-4b01-b3a9-cc9d380e8caa

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.7 years (5,373 days).

Biospecimens (3 samples)
- Sample 0DECX0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DECXC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DECYM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
